Somatic mutation profile of cancer-model specimen HCM-SANG-0282-C18-85B (3D Organoid; aliquot HCM-SANG-0282-C18-85B-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0282-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0282-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16b5c224-ee5d-4e93-a1db-66dda25a2a2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0282-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0282-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aee20f73-cebb-4347-9167-b1e05a09d91c

The open-access MAF lists 2,636 somatic variants for this specimen: 1,932 protein-altering or splice-affecting, 591 silent, 113 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,393, Silent 591, Frame Shift Del 310, Frame Shift Ins 84, Nonsense Mutation 77, Intron 64, In Frame Del 22, Splice Site 21, Splice Region 19, 3'UTR 17, 5'Flank 13, 5'UTR 10.

Variants (750 of 2,636; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.4124C>T p.A1375V | Missense Mutation (SNP) | VAF 83/417 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1267585230; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/207 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BTD | c.1569C>A p.D523E | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs146136265, CM148364; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 100/200 reads (50%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- CHD7 | c.1925del p.K642Rfs*69 | Frame Shift Del (DEL) | VAF 152/361 reads (42%) | catalogued as rs1554588712; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL18A1 | c.3918dup p.G1307Rfs*9 (on ENST00000359759 / NM_130444.3; = p.G1072Rfs*9 on NM_030582.4) | Frame Shift Ins (INS) | VAF 96/523 reads (18%) | catalogued as rs749009747; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTSA | c.517_518del p.F173Pfs*39 | Frame Shift Del (DEL) | VAF 78/635 reads (12%) | catalogued as rs769812697; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GFM1 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs143031224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IRF6 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 259/560 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553248641, CM044897, COSV65419612, COSV65420517; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 212/424 reads (50%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MAPK8IP3 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 117/720 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1567203083; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 191/428 reads (45%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MFRP | chr11:119346148 G>A | 5'Flank (SNP) | VAF 310/634 reads (49%) | catalogued as rs1422497202; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 73/340 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs63750781, CM950802, CM960965, COSV51617070; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2191dup p.R731Pfs*62 | Frame Shift Ins (INS) | VAF 133/652 reads (20%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.332_334del p.K111del | In Frame Del (DEL) | VAF 37/216 reads (17%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 78/246 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SHOX | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 471/934 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs886043634, CM056986, CM070262, CM074516; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 95/485 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AAGAB | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99971832; called by muse, varscan2
- AAMP | c.1160C>A p.A387D | Missense Mutation (SNP) | VAF 456/879 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV99946221; called by muse, mutect2, varscan2
- ABCA3 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 273/515 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368830525; called by muse, mutect2, varscan2
- ABCB5 | c.3488G>A p.R1163K (on ENST00000404938 / NM_001163941.2; = p.R718K on NM_178559.6) | Missense Mutation (SNP) | VAF 81/357 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51710752; called by muse, mutect2, varscan2
- ABCD1 | c.218A>G p.Q73R | Missense Mutation (SNP) | VAF 468/996 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1557052252; called by muse, varscan2
- ACOX3 | c.1978G>A p.G660S | Missense Mutation (SNP) | VAF 209/446 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177495988; called by muse, mutect2, varscan2
- ACTN2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 233/471 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs574401232, COSV63974769, COSV63976641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTRT1 | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 160/756 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64420255; called by muse, mutect2, varscan2
- ADAM33 | c.101A>T p.H34L | Missense Mutation (SNP) | VAF 73/483 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62933856; called by muse, mutect2, varscan2
- ADAMTS7 | c.4237G>A p.A1413T | Missense Mutation (SNP) | VAF 104/669 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs779347806, COSV101183277; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1506G>T p.E502D | Missense Mutation (SNP) | VAF 113/232 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771228624; called by muse, mutect2, varscan2
- ADAP2 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 25/880 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1017475668; called by muse, mutect2
- ADCY10 | c.4790dup p.N1597Kfs*8 | Frame Shift Ins (INS) | VAF 146/270 reads (54%) | catalogued as rs753500756; called by mutect2, varscan2
- ADCY10 | c.3063del p.P1022Lfs*9 | Frame Shift Del (DEL) | VAF 133/349 reads (38%) | catalogued as rs764365704; called by mutect2, pindel, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 43/236 reads (18%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRG4 | c.8794C>T p.R2932W | Missense Mutation (SNP) | VAF 131/477 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs201655013; called by muse, varscan2
- ADH1B | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV59294977; called by muse, mutect2, varscan2
- ADH1C | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 154/722 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV72463381; called by muse, mutect2
- ADPRHL1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 102/602 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs533507871; called by muse, mutect2, varscan2
- AFTPH | c.644A>G p.H215R | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs201836808; called by muse, mutect2, varscan2
- AGRN | c.4705G>A p.A1569T | Missense Mutation (SNP) | VAF 341/729 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1272870747; called by muse, mutect2, varscan2
- AL121899.2 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 185/389 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772095348, COSV67351818; called by muse, mutect2, varscan2
- AL162417.1 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 134/276 reads (49%) | catalogued as rs1341678383; called by muse, mutect2, varscan2
- ALKBH5 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 30/1136 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV67687282; called by muse, mutect2
- ALOX5 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 257/923 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750603646; called by muse, mutect2, varscan2
- ALPI | c.648C>T p.D216= | Splice Region (SNP) | VAF 244/475 reads (51%) | catalogued as rs567263838, COSV55016071; called by muse, mutect2, varscan2
- ALPL | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 371/771 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs138690664, CM980079; called by muse, mutect2, varscan2
- ANGPTL8 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 115/734 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.133); catalogued as rs79566395, COSV99371064; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 117/283 reads (41%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 176/358 reads (49%) | catalogued as rs370637835; called by mutect2, varscan2
- ANKMY1 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 301/640 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV56035652; called by muse, mutect2, varscan2
- ANKRD30A | c.1573-1G>T p.X525_splice (on ENST00000611781; = p.X469_splice on NM_052997.2) | Splice Site (SNP) | VAF 111/206 reads (54%) | catalogued as COSV100653965, COSV64603630; called by muse, mutect2, varscan2
- ANKRD34B | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 89/332 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs763836907; called by muse, mutect2, varscan2
- ANKRD50 | c.1960G>T p.G654* | Nonsense Mutation (SNP) | VAF 246/494 reads (50%) | catalogued as COSV101538993; called by muse, mutect2
- ANKRD6 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 134/325 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs369619069, COSV60237478; called by muse, mutect2, varscan2
- ANO5 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV61088180, COSV61089354; called by muse, mutect2, varscan2
- ANTXR1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 112/271 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765361538, COSV58014385; called by muse, mutect2, varscan2
- AP3D1 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 405/828 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1049141059; called by muse, mutect2, varscan2
- AP3S1 | c.380del p.G127Efs*8 | Frame Shift Del (DEL) | VAF 68/176 reads (39%) | catalogued as rs1253149765; called by mutect2, pindel, varscan2
- AP5Z1 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 248/515 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs889288295; called by muse, mutect2, varscan2
- AP5Z1 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 436/907 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs746835930, COSV62242141; called by muse, mutect2, varscan2
- APP | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 98/598 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs200159151, COSV100695161; called by muse, varscan2
- APPBP2 | c.1220A>G p.H407R | Missense Mutation (SNP) | VAF 125/242 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1386714000; called by muse, mutect2, varscan2
- AQP3 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 307/614 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374165388; called by muse, mutect2, varscan2
- ARHGAP20 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 252/495 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs777145556; called by muse, mutect2, varscan2
- ARHGAP20 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 274/542 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52812295; called by muse, mutect2, varscan2
- ARHGAP24 | c.1255A>G p.M419V (on ENST00000395184 / NM_001025616.3; = p.M326V on NM_031305.3) | Missense Mutation (SNP) | VAF 124/410 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51992125; called by muse, mutect2, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 348/899 reads (39%) | catalogued as COSV57429840; called by mutect2, pindel, varscan2
- ARHGEF16 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 257/569 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs766009040; called by muse, mutect2, varscan2
- ARID1A | c.268A>G p.S90G | Missense Mutation (SNP) | VAF 550/1230 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs752026201, COSV61381821; ClinVar: likely benign; called by mutect2, varscan2
- ARID1B | c.4322C>T p.S1441L | Missense Mutation (SNP) | VAF 397/783 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV51682298; called by muse, mutect2, varscan2
- ARID1B | c.5765C>T p.A1922V | Missense Mutation (SNP) | VAF 317/673 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1282942992, COSV51657347; called by muse, mutect2, varscan2
- ARMC5 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 412/889 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs756654607, COSV99192302; called by muse, mutect2, varscan2
- ARPC5L | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 110/586 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1417524107; called by muse, mutect2, varscan2
- ARSG | c.1507T>C p.Y503H | Missense Mutation (SNP) | VAF 320/616 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV50931703; called by muse, varscan2
- ARVCF | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 108/596 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs141228868; called by muse, mutect2, varscan2
- ASAP1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1272837459; called by muse, mutect2, varscan2
- ASB14 | c.202C>T p.H68Y (on ENST00000389601; = p.H67Y on NM_001142733.3) | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1354498544; called by muse, mutect2, varscan2
- ASB15 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 147/301 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs370081452; called by muse, mutect2
- ASNSD1 | c.1617_1618del p.R539Sfs*4 | Frame Shift Del (DEL) | VAF 132/362 reads (36%) | catalogued as rs761125104; called by pindel, varscan2
- ASPSCR1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 229/468 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs1249773314, COSV60727228; called by muse, mutect2
- ASTN1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 321/744 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs760958680, COSV56070701; called by muse, mutect2
- ATE1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs769808653; called by muse, mutect2, varscan2
- ATOH1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 440/857 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1026411537; called by muse, mutect2, varscan2
- ATP11A | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 163/738 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs780037254, COSV99369340; called by muse, mutect2, varscan2
- ATP13A4 | c.2581G>A p.V861M | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs143538005; called by muse, mutect2, varscan2
- ATP2A2 | c.2963G>A p.R988H | Missense Mutation (SNP) | VAF 345/693 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757225415, COSV104394056; called by muse, mutect2, varscan2
- ATP2C2 | c.1742G>A p.G581D | Missense Mutation (SNP) | VAF 135/760 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1370537578; called by muse, mutect2, varscan2
- ATP8B1 | c.1628A>G p.D543G | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.246); catalogued as COSV52172968; called by muse, mutect2, varscan2
- ATPSCKMT | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 115/374 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1296572911, COSV99725879; called by muse, mutect2, varscan2
- AURKB | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 123/480 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.296); catalogued as rs1454860641; called by muse, mutect2, varscan2
- AUTS2 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 72/375 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV61382567; called by muse, mutect2, varscan2
- AXIN1 | c.792del p.G265Efs*149 | Frame Shift Del (DEL) | VAF 280/693 reads (40%) | catalogued as COSV51989295; called by mutect2, pindel, varscan2
- B4GALNT2 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 295/590 reads (50%) | catalogued as rs201141534, COSV55924371; called by muse, varscan2
- BAIAP3 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 342/696 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs1445556722, COSV50106131; called by muse, mutect2, varscan2
- BANP | c.185G>A p.S62N (on ENST00000286122; = p.S70N on NM_017869.4) | Missense Mutation (SNP) | VAF 162/365 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.958); catalogued as rs1327419986; called by muse, mutect2, varscan2
- BAP1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 233/506 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs199564379, COSV56238827, COSV56239952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARHL1 | c.946dup p.L316Pfs*69 | Frame Shift Ins (INS) | VAF 374/781 reads (48%) | catalogued as rs752703018; called by mutect2, varscan2
- BCAM | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 376/752 reads (50%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs139845447; called by muse, mutect2, varscan2
- BCAT2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 272/587 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436813338, COSV60271662; called by muse, mutect2, varscan2
- BCL11A | c.1136C>T p.A379V (on ENST00000335712 / NM_001365609.1; = p.A413V on NM_018014.4) | Missense Mutation (SNP) | VAF 27/839 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59627256; called by muse, mutect2
- BCLAF1 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs767744483, COSV62141838, COSV62145565, COSV62146283; called by muse, mutect2, varscan2
- BDP1 | c.2930C>T p.T977I | Missense Mutation (SNP) | VAF 79/395 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs747616595; called by muse, mutect2, varscan2
- BICDL1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 224/428 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs779640650, COSV66908238; called by muse, mutect2, varscan2
- BICRA | c.3659G>A p.R1220Q | Missense Mutation (SNP) | VAF 169/941 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.657); catalogued as rs773367025, COSV99064107; called by muse, mutect2, varscan2
- BIN1 | c.1492T>C p.F498L (on ENST00000316724 / NM_001320642.1; = p.F359L on NM_004305.4) | Missense Mutation (SNP) | VAF 46/736 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.212); catalogued as rs368238742; called by muse, mutect2
- BMP4 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 95/192 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750868626, COSV55417535; called by muse, mutect2, varscan2
- BMPR2 | c.796_799del p.R266Sfs*12 | Frame Shift Del (DEL) | VAF 168/375 reads (45%) | catalogued as rs1085307261; called by mutect2, pindel, varscan2
- BMS1 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs544576935; called by muse, mutect2, varscan2
- BPIFB4 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 138/629 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs752406178, COSV64950589, COSV64950633; called by muse, varscan2
- BRI3BP | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 334/711 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); catalogued as rs779314883, COSV58297634; called by muse, mutect2, varscan2
- BRINP1 | c.1431del p.F477Lfs*12 | Frame Shift Del (DEL) | VAF 296/756 reads (39%) | catalogued as COSV56291439; called by mutect2, pindel, varscan2
- BRINP2 | c.661del p.A221Pfs*53 | Frame Shift Del (DEL) | VAF 174/447 reads (39%) | catalogued as COSV64180297; called by mutect2, pindel, varscan2
- BSN | c.7666C>T p.R2556W | Missense Mutation (SNP) | VAF 329/676 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV56513509; called by muse, mutect2, varscan2
- BSN | c.10330C>T p.R3444W | Missense Mutation (SNP) | VAF 380/732 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs780861870, COSV56526209; called by muse, varscan2
- BTBD7 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 18/542 reads (3%) | catalogued as rs987046202; called by muse, mutect2
- C12orf45 | c.551del p.K184Rfs*13 | Frame Shift Del (DEL) | VAF 96/169 reads (57%) | catalogued as rs777032057; called by mutect2, varscan2
- C12orf65 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 214/501 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374311195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C19orf38 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 189/412 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1360274869; called by muse, mutect2, varscan2
- C19orf47 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 91/713 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63508431; called by muse, mutect2, varscan2
- C1orf87 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 159/399 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs139412338, COSV64596122; called by muse, mutect2, varscan2
- C20orf203 | c.316del p.E106Kfs*73 | Frame Shift Del (DEL) | VAF 219/523 reads (42%) | catalogued as rs1568750079; called by mutect2, pindel, varscan2
- C2CD3 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV58096274; called by muse, mutect2, varscan2
- C6 | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 157/353 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV54711698, COSV99667499; called by muse, mutect2, varscan2
- C6orf132 | c.1344del p.S449Afs*68 | Frame Shift Del (DEL) | VAF 292/557 reads (52%) | catalogued as rs774701362; called by mutect2, varscan2
- C6orf132 | c.680dup p.P228Tfs*55 | Frame Shift Ins (INS) | VAF 106/272 reads (39%) | catalogued as rs772488732; called by mutect2, varscan2
- CA5B | c.715C>A p.L239I | Missense Mutation (SNP) | VAF 295/586 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV59417071; called by muse, mutect2, varscan2
- CABP4 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 400/883 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs752839228; called by muse, mutect2, varscan2
- CACNA1A | c.7454C>T p.A2485V | Missense Mutation (SNP) | VAF 134/807 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs758817759; called by muse, varscan2
- CACNA1C | c.5110G>A p.G1704S | Missense Mutation (SNP) | VAF 260/563 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs758268349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB1 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 104/673 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV59998707; called by muse, mutect2, varscan2
- CACNB1 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 178/904 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779454713; called by muse, varscan2
- CACNG6 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 398/771 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs1235805731; called by muse, mutect2, varscan2
- CADM2 | c.301C>A p.Q101K (on ENST00000407528 / NM_001167674.2; = p.Q103K on NM_153184.4) | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.43); catalogued as COSV101057030; called by muse, mutect2, varscan2
- CAMK1G | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 59/444 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as rs1434206258; called by muse, mutect2, varscan2
- CAMSAP1 | c.3098C>T p.T1033M | Missense Mutation (SNP) | VAF 262/562 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs753486145; called by muse, mutect2, varscan2
- CAMTA2 | c.3239G>A p.R1080H | Missense Mutation (SNP) | VAF 97/534 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs200331429; called by muse, mutect2, varscan2
- CAPN12 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 401/822 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs748626356; called by muse, mutect2, varscan2
- CAPN9 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 225/517 reads (44%) | catalogued as rs559454208, COSV55231581; called by muse, mutect2, varscan2
- CASP1 | c.689C>T p.T230M (on ENST00000436863 / NM_033292.4; = p.T209M on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 173/418 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs878955041, COSV62056170; called by muse, mutect2, varscan2
- CATSPER4 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 326/674 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs757319008, COSV58792300; called by muse, mutect2, varscan2
- CAVIN2 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 105/535 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV58423185; called by muse, mutect2
- CBX1 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 19/638 reads (3%) | catalogued as COSV56681749, COSV56682056; called by muse, mutect2
- CCDC138 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs748883294; called by muse, mutect2, varscan2
- CCDC141 | c.4465G>A p.A1489T | Missense Mutation (SNP) | VAF 272/587 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1017036149; called by muse, mutect2, varscan2
- CCDC158 | c.3328dup p.M1110Nfs*20 | Frame Shift Ins (INS) | VAF 36/240 reads (15%) | catalogued as rs762322126; called by mutect2, pindel, varscan2
- CCDC73 | c.2234del p.G745Efs*8 | Frame Shift Del (DEL) | VAF 51/259 reads (20%) | catalogued as COSV58799359; called by mutect2, pindel, varscan2
- CCDC73 | c.2014del p.S672Vfs*22 | Frame Shift Del (DEL) | VAF 88/243 reads (36%) | catalogued as rs747131147; called by mutect2, pindel, varscan2
- CCS | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 115/648 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331010335; called by muse, mutect2, varscan2
- CD200R1L | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1417229171; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 160/658 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- CD248 | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 452/962 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.919); catalogued as rs539641105, COSV60935987; called by muse, mutect2
- CDC42EP4 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 380/798 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs1412267800, COSV59961983; called by muse, mutect2, varscan2
- CDH10 | c.1577del p.F526Sfs*3 | Frame Shift Del (DEL) | VAF 92/202 reads (46%) | catalogued as rs1209448007; called by mutect2, varscan2
- CDH20 | c.1949A>G p.Y650C | Missense Mutation (SNP) | VAF 214/458 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs767247001, COSV99406778; called by muse, mutect2, varscan2
- CDHR2 | c.3592G>A p.A1198T | Missense Mutation (SNP) | VAF 52/461 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56139972; called by muse, mutect2, varscan2
- CDHR5 | c.1526C>T p.S509L (on ENST00000358353 / NM_001171968.2; = p.S515L on NM_021924.5) | Missense Mutation (SNP) | VAF 618/1243 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs184842479; called by muse, varscan2
- CDK11A | c.110del p.N37Ifs*17 | Frame Shift Del (DEL) | VAF 36/149 reads (24%) | catalogued as rs767014805; called by mutect2, varscan2
- CDK5R2 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 353/739 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1325125568; called by muse, mutect2, varscan2
- CELSR3 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 357/711 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1243919332; called by muse, mutect2, varscan2
- CENPE | c.4252A>G p.R1418G | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as COSV54375556; called by muse, mutect2
- CENPE | c.1907A>G p.D636G | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751194057; called by muse, mutect2, varscan2
- CEP162 | c.1354dup p.I452Nfs*4 | Frame Shift Ins (INS) | VAF 67/172 reads (39%) | catalogued as rs754003632; called by mutect2, varscan2
- CEP192 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 106/214 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs752095796, COSV58061853; called by muse, mutect2, varscan2
- CFAP47 | c.9491G>A p.R3164H | Missense Mutation (SNP) | VAF 143/306 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1166928928, COSV66221408; called by muse, mutect2, varscan2
- CFAP65 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 312/682 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs138095762; called by muse, mutect2, varscan2
- CFAP65 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 408/792 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs772103989, COSV58562929; called by muse, mutect2, varscan2
- CFAP74 | c.4462del p.L1488Wfs*8 | Frame Shift Del (DEL) | VAF 318/788 reads (40%) | catalogued as rs753357875; called by mutect2, pindel, varscan2
- CFP | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 481/1007 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1444150137, COSV55951178; called by muse, mutect2, varscan2
- CGB2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 124/674 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs1341598546; called by muse, mutect2, varscan2
- CHD6 | c.6286G>A p.V2096M | Missense Mutation (SNP) | VAF 129/285 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs369614239; called by muse, mutect2, varscan2
- CHD8 | c.7181A>G p.K2394R (on ENST00000646647 / NM_001170629.2; = p.K2115R on NM_020920.4) | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV63036921; called by muse, mutect2, varscan2
- CHPF2 | c.889T>C p.S297P | Missense Mutation (SNP) | VAF 84/626 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV50394240; called by muse, mutect2, varscan2
- CHRNA1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 35/579 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs777813669; ClinVar: uncertain significance; called by muse, mutect2
- CIAO1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 214/497 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.869); catalogued as rs367694646; called by muse, mutect2, varscan2
- CILP2 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 465/969 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52276128; called by muse, mutect2, varscan2
- CKAP2 | c.1021G>A p.V341I (on ENST00000378037 / NM_001098525.2; = p.V340I on NM_018204.5) | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776766061; called by muse, mutect2, varscan2
- CKAP4 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 95/740 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs776548460; called by muse, mutect2, varscan2
- CLCN1 | c.2578G>A p.V860I | Missense Mutation (SNP) | VAF 209/483 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs767209392, COSV58374909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMYA5 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 138/281 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773904463, COSV71404679; called by muse, mutect2, varscan2
- CNBD1 | c.806T>G p.V269G | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.282); catalogued as COSV73072512; called by muse, mutect2, varscan2
- CNTN5 | c.1199A>G p.Q400R | Missense Mutation (SNP) | VAF 114/268 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.259); catalogued as rs1431729010; called by muse, mutect2, varscan2
- CNTNAP5 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 93/519 reads (18%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); catalogued as rs1172484897, COSV101443186, COSV70482372; called by muse, mutect2, varscan2
- COG6 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 56/728 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs886050224, COSV62998584; ClinVar: uncertain significance; called by muse, mutect2
- COL12A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 37/782 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.192); catalogued as rs779083996, COSV100486824, COSV59396626; called by muse, mutect2
- COL16A1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 386/726 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs183118523; called by muse, mutect2, varscan2
- COL26A1 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 277/599 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747060134, COSV58133035; called by muse, mutect2, varscan2
- COL3A1 | c.3298C>T p.R1100C | Missense Mutation (SNP) | VAF 101/517 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs755321924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.4886C>T p.T1629M | Missense Mutation (SNP) | VAF 201/429 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762126668; called by muse, mutect2, varscan2
- COL6A6 | c.3718G>T p.A1240S | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62035636; called by muse, mutect2, varscan2
- COL8A2 | c.281del p.P94Lfs*143 | Frame Shift Del (DEL) | VAF 354/818 reads (43%) | catalogued as rs1277273445; called by mutect2, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 46/300 reads (15%) | catalogued as COSV101232229; called by mutect2, pindel, varscan2
- CPAMD8 | c.2764G>A p.V922I (on ENST00000651564; = p.V875I on NM_015692.5) | Missense Mutation (SNP) | VAF 117/592 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.789); catalogued as rs199613595, COSV71595963; called by muse, mutect2, varscan2
- CPSF1 | c.1637_1638+1del p.X546_splice | Splice Site (DEL) | VAF 250/526 reads (48%) | catalogued as rs1321162482; called by pindel, varscan2
- CPSF2 | c.1654del p.I552Sfs*5 | Frame Shift Del (DEL) | VAF 68/541 reads (13%) | catalogued as rs758712860; called by mutect2, pindel, varscan2
- CPXCR1 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 158/383 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV52164607; called by muse, mutect2
- CPXM2 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 304/636 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1327378582, COSV53862587; called by mutect2, varscan2
- CRAMP1 | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 397/794 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394579767; called by muse, mutect2, varscan2
- CRB2 | c.117del p.S40Vfs*102 | Frame Shift Del (DEL) | VAF 137/684 reads (20%) | catalogued as COSV63505201; called by mutect2, pindel, varscan2
- CROCC | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 93/899 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as rs775591348; called by muse, mutect2, varscan2
- CRYM | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 224/519 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs756499307; called by muse, mutect2, varscan2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 202/1036 reads (19%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 66/209 reads (32%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.10224C>A p.P3408= (on ENST00000297405 / NM_001363185.1; = p.P3239= on NM_052900.3) | Splice Region (SNP) | VAF 23/183 reads (13%) | catalogued as COSV52313582; called by muse, mutect2, varscan2
- CSNK1D | c.179A>T p.Q60L | Missense Mutation (SNP) | VAF 117/243 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as rs1484202328; called by muse, mutect2, varscan2
- CSPG4 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 331/732 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV100413200; called by muse, mutect2, varscan2
- CTAG2 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 179/634 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs782803654; called by muse, mutect2, varscan2
- CTBP2 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 164/370 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as COSV58333245, COSV58335458; called by muse, varscan2
- CTNNA2 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 19/445 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV63570435; called by muse, mutect2
- CTNNA2 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 148/338 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.169); catalogued as rs764740838, COSV58163403; called by muse, mutect2, varscan2
- CTNND1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 281/553 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs746989296; called by muse, mutect2, varscan2
- CTR9 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs751136727; called by muse, mutect2, varscan2
- CTSC | c.1033T>C p.Y345H | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1422115423; called by muse, mutect2, varscan2
- CYB5D2 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 280/621 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs367926129; called by muse, mutect2, varscan2
- CYLC1 | c.1193del p.K398Rfs*95 | Frame Shift Del (DEL) | VAF 79/348 reads (23%) | catalogued as COSV104412456; called by pindel, varscan2
- CYLC1 | c.1271del p.K424Rfs*69 | Frame Shift Del (DEL) | VAF 134/382 reads (35%) | catalogued as rs1385226543; called by pindel, varscan2
- CYP21A2 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 115/624 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.738); catalogued as rs528524868, COSV64478396; called by mutect2, varscan2
- CYP26C1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 539/1055 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.172); catalogued as rs779223251; called by muse, mutect2, varscan2
- CYP2A13 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 216/510 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV57836753; called by muse, mutect2, varscan2
- CYP2C19 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 271/563 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150152656, CM1510895; called by muse, mutect2, varscan2
- CYP3A7 | c.1097T>C p.L366S | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60481925; called by muse, mutect2, varscan2
- CYSRT1 | c.463G>A p.A155T (on ENST00000409414; = p.A115T on NM_199001.5) | Missense Mutation (SNP) | VAF 594/1174 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs891633307, COSV100746698; called by muse, mutect2, varscan2
- D2HGDH | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 239/479 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs868052442; called by muse, mutect2, varscan2
- DACT3 | c.935del p.G312Afs*9 | Frame Shift Del (DEL) | VAF 315/804 reads (39%) | catalogued as rs1323152884; called by mutect2, pindel, varscan2
- DAND5 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 359/821 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1568238076; called by muse, mutect2, varscan2
- DBX1 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 443/913 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs1453851303; called by muse, mutect2, varscan2
- DCAF4L1 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 268/538 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs749280519, COSV60787209; called by muse, mutect2, varscan2
- DCAF8L1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 42/714 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs778270304, COSV71595185; called by muse, mutect2
- DCAF8L2 | c.432_437del p.E146_E147del | In Frame Del (DEL) | VAF 77/618 reads (12%) | catalogued as rs773661469; called by pindel, varscan2
- DCLK1 | c.1800G>C p.Q600H | Missense Mutation (SNP) | VAF 150/324 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV55174478; called by muse, mutect2, varscan2
- DCTN1 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 251/500 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100720842; called by muse, mutect2, varscan2
- DCTN5 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55616196; called by muse, mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 28/163 reads (17%) | catalogued as rs773554787; called by mutect2, pindel, varscan2
- DENND3 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 242/484 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs200436717, COSV99370677; called by muse, mutect2, varscan2
- DENND3 | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 122/710 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.634); catalogued as rs374820736; called by muse, varscan2
- DEPDC1 | c.1864C>T p.R622C (on ENST00000456315 / NM_001114120.3; = p.R338C on NM_017779.6) | Missense Mutation (SNP) | VAF 143/301 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as rs200248484, COSV63957627; called by muse, mutect2, varscan2
- DGAT1 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 274/559 reads (49%) | catalogued as rs782733856; called by pindel, varscan2
- DHX29 | c.1737C>A p.D579E | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1231732389; called by muse, mutect2, varscan2
- DIDO1 | c.4394C>T p.A1465V | Missense Mutation (SNP) | VAF 164/827 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV56629502; called by muse, mutect2, varscan2
- DIPK1B | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 382/781 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs564982211; called by muse, mutect2, varscan2
- DISP2 | c.2849G>A p.R950H | Missense Mutation (SNP) | VAF 117/748 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs780839027, COSV51126407, COSV51137370; called by muse, mutect2, varscan2
- DLG5 | c.4442dup p.A1482Sfs*51 | Frame Shift Ins (INS) | VAF 270/638 reads (42%) | catalogued as rs778796396; called by mutect2, varscan2
- DLK1 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 811/1311 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769339902; called by muse, mutect2
- DNAH1 | c.6154G>A p.V2052I | Missense Mutation (SNP) | VAF 209/403 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs745938182, COSV70226906, COSV70227690; called by muse, mutect2, varscan2
- DNAH10 | c.2221T>G p.L741V (on ENST00000409039; = p.L680V on NM_207437.3) | Missense Mutation (SNP) | VAF 190/410 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs373509532; called by muse, mutect2, varscan2
- DNAH17 | c.11396G>A p.R3799H | Missense Mutation (SNP) | VAF 189/658 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs538298703, COSV67755242; called by muse, mutect2, varscan2
- DNAH17 | c.4442C>T p.T1481M | Missense Mutation (SNP) | VAF 150/694 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs370414556; called by muse, mutect2, varscan2
- DNAH5 | c.7361T>C p.V2454A | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1487855713, COSV54226760; called by muse, mutect2, varscan2
- DNAH5 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 146/312 reads (47%) | catalogued as rs1314223921, CM065118, COSV54247530; called by muse, mutect2, varscan2
- DNAJC4 | c.381del p.N128Tfs*11 | Frame Shift Del (DEL) | VAF 150/630 reads (24%) | catalogued as rs1000579773; called by mutect2, pindel, varscan2
- DNHD1 | c.12197G>A p.R4066Q | Missense Mutation (SNP) | VAF 85/684 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs370859986; called by muse, mutect2, varscan2
- DNMT3A | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 178/942 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53046433; called by muse, mutect2, varscan2
- DNTTIP2 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100785189; called by muse, mutect2, varscan2
- DOCK1 | c.3752A>T p.E1251V | Missense Mutation (SNP) | VAF 40/483 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV54742839; called by muse, mutect2
- DOCK4 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 167/345 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1482222418; called by muse, mutect2, varscan2
- DOP1B | c.3557C>T p.T1186M | Missense Mutation (SNP) | VAF 147/782 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478524066; called by muse, mutect2, varscan2
- DPP4 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1209315967, COSV100859019; called by muse, mutect2, varscan2
- DPP8 | c.422C>T p.A141V (on ENST00000341861 / NM_001320875.2; = p.A125V on NM_017743.6) | Missense Mutation (SNP) | VAF 102/200 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1237594665; called by muse, mutect2, varscan2
- DPY19L3 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1042584324; called by muse, mutect2, varscan2
- DROSHA | c.3653C>T p.A1218V | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60780026; called by muse, mutect2
- DSG3 | c.2144G>A p.G715D | Missense Mutation (SNP) | VAF 192/410 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs367712383; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs571244328; called by muse, mutect2, varscan2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 63/132 reads (48%) | catalogued as rs752987091; called by mutect2, varscan2
- ECT2 | c.480del p.G161Efs*16 (on ENST00000392692 / NM_001349098.2; = p.G130Efs*16 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 83/207 reads (40%) | catalogued as COSV51691378; called by mutect2, pindel, varscan2
- EFS | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 132/631 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1246258959; called by muse, mutect2, varscan2
- EIF4E1B | c.474G>T p.T158= | Splice Region (SNP) | VAF 188/406 reads (46%) | catalogued as COSV53781486; called by muse, mutect2, varscan2
- EIF5A | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 296/608 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs769669056, COSV59746693; called by muse, varscan2
- EMC1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs540043483; called by muse, mutect2, varscan2
- EN2 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 308/640 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52082876; called by muse, mutect2, varscan2
- ENTPD5 | c.1043del p.G348Vfs*3 | Frame Shift Del (DEL) | VAF 83/305 reads (27%) | catalogued as COSV58224109; called by mutect2, pindel, varscan2
- EOMES | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 44/1236 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1161870197; called by muse, mutect2
- EPHA3 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 164/340 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs772463834, COSV60692526; called by muse, mutect2, varscan2
- EPHA5 | c.2658+1G>A p.X886_splice | Splice Site (SNP) | VAF 30/210 reads (14%) | catalogued as COSV56650388; called by muse, mutect2, varscan2
- EPHB4 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 199/400 reads (50%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.718); catalogued as rs1463123787, COSV62269760; called by muse, mutect2, varscan2
- ERAL1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 168/373 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs368942957; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1123C>A p.L375I | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.603); catalogued as rs1294123758; called by muse, mutect2
- ESS2 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 315/656 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs200628413, COSV52816430; called by muse, mutect2, varscan2
- ETV6 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 231/727 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs150089916, CM156387, COSV67150627; called by muse, mutect2, varscan2
- EVI5 | c.648del p.F216Lfs*15 | Frame Shift Del (DEL) | VAF 79/336 reads (24%) | catalogued as rs1453325274; called by mutect2, pindel, varscan2
- EXOC3 | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 268/524 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.351); catalogued as rs1433915091; called by muse, mutect2, varscan2
- EXOC3L4 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 169/1389 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66295499; called by muse, mutect2, varscan2
- F10 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 60/505 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs121964939, CM900083, COSV65021159; called by muse, mutect2, varscan2
- F2R | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 177/413 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196477577, COSV59929723; called by muse, mutect2, varscan2
- F8 | c.1443+1G>T p.X481_splice | Splice Site (SNP) | VAF 101/222 reads (45%) | catalogued as CS073483, CS080693, CS962660; called by muse, mutect2, varscan2
- FAM104A | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 242/619 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1169974427; called by muse, mutect2, varscan2
- FAM131C | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 142/776 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs1189832298; called by muse, mutect2, varscan2
- FAM166A | c.558del p.A187Pfs*8 | Frame Shift Del (DEL) | VAF 212/441 reads (48%) | catalogued as rs766839703; called by mutect2, pindel, varscan2
- FAM168A | c.586G>T p.G196C (on ENST00000064778 / NM_001286050.2; = p.G187C on NM_015159.3) | Missense Mutation (SNP) | VAF 26/716 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99291491; called by muse, mutect2
- FAM170B | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 22/757 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1280173439; called by muse, mutect2
- FAM228B | c.687-1G>T p.X229_splice | Splice Site (SNP) | VAF 67/210 reads (32%) | catalogued as rs768837519; called by muse, mutect2, varscan2
- FAM47A | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 412/856 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1479912221, COSV60496040; called by muse, mutect2, varscan2
- FAM47A | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 133/724 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60494427; called by muse, mutect2, varscan2
- FAM47C | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 216/985 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as rs1556332457, COSV63725336; called by muse, mutect2, varscan2
- FAM98C | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 157/720 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs748537969, COSV53039265; called by muse, mutect2, varscan2
- FAP | c.923G>T p.W308L | Missense Mutation (SNP) | VAF 148/317 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV51867503; called by muse, mutect2, varscan2
- FASN | c.7516G>A p.V2506M | Missense Mutation (SNP) | VAF 302/683 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.964); catalogued as rs766210377, COSV60757590; called by muse, mutect2, varscan2
- FASN | c.1236del p.A413Hfs*39 | Frame Shift Del (DEL) | VAF 200/961 reads (21%) | catalogued as COSV60760319; called by mutect2, pindel, varscan2
- FASTKD5 | c.2000del p.G667Afs*6 | Frame Shift Del (DEL) | VAF 208/780 reads (27%) | catalogued as rs1233549844; called by mutect2, pindel, varscan2
- FAT1 | c.11737G>A p.A3913T | Missense Mutation (SNP) | VAF 211/428 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs773650405, COSV101499198; called by muse, mutect2, varscan2
- FAT1 | c.724A>T p.K242* | Nonsense Mutation (SNP) | VAF 97/566 reads (17%) | catalogued as COSV101499096; called by muse, mutect2, varscan2
- FAT3 | c.11389G>A p.D3797N | Missense Mutation (SNP) | VAF 64/437 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.511); catalogued as rs771733194, COSV53132862, COSV53134863; called by muse, mutect2, varscan2
- FAT4 | c.14857G>A p.A4953T | Missense Mutation (SNP) | VAF 162/347 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1244653699, COSV58688357; called by muse, mutect2, varscan2
- FBRSL1 | c.2739del p.A914Pfs*90 | Frame Shift Del (DEL) | VAF 227/918 reads (25%) | catalogued as rs1566257864; called by mutect2, pindel, varscan2
- FBXL7 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 140/709 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs762341690, COSV61641347; called by muse, varscan2
- FBXL7 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 374/732 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1026833800, COSV61650185; called by muse, varscan2
- FBXW4 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 128/541 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs746642677; called by muse, mutect2, varscan2
- FCAMR | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 195/410 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as COSV61367261; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 52/122 reads (43%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FER1L6 | c.5482G>A p.A1828T | Missense Mutation (SNP) | VAF 86/499 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as rs190098903; called by muse, mutect2, varscan2
- FGB | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 222/419 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as rs1338330939; called by muse, mutect2, varscan2
- FGGY | c.1392del p.F464Lfs*47 | Frame Shift Del (DEL) | VAF 72/277 reads (26%) | catalogued as rs1279718607; called by mutect2, pindel, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 69/450 reads (15%) | catalogued as rs749851531; called by mutect2, pindel, varscan2
- FKRP | c.948del p.C317Afs*111 | Frame Shift Del (DEL) | VAF 118/790 reads (15%) | catalogued as rs748798133, CM0910304; called by mutect2, pindel, varscan2
- FLNA | c.7195G>A p.V2399I (on ENST00000369850 / NM_001110556.2; = p.V2391I on NM_001456.3) | Missense Mutation (SNP) | VAF 381/789 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs878854463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNA | c.2614G>A p.A872T | Missense Mutation (SNP) | VAF 397/727 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs185503240, COSV61048854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.7423G>A p.V2475I | Missense Mutation (SNP) | VAF 136/703 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs191224002, COSV100368176, COSV57967350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLOT1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 67/902 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV99458145; called by muse, mutect2
- FOXI3 | c.92dup p.A32Gfs*147 | Frame Shift Ins (INS) | VAF 70/246 reads (28%) | catalogued as rs1558612214; called by mutect2, varscan2
- FOXL2 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 528/1089 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs776277339; called by muse, mutect2, varscan2
- FRS3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 134/720 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1456418511, COSV99442556; called by muse, varscan2
- FSD1 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 205/437 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs189542513, COSV55697747; called by muse, mutect2, varscan2
- FUS | c.1397del p.X466_splice | Splice Site (DEL) | VAF 170/620 reads (27%) | catalogued as rs35711706; called by mutect2, pindel, varscan2
- GADL1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 137/282 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.13); catalogued as rs1001938718, COSV56975176; called by muse, mutect2, varscan2
- GALNT16 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 34/581 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776680086; called by muse, mutect2
- GAPDHS | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 183/387 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as rs750934612; called by muse, mutect2, varscan2
- GCFC2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 346/720 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as rs898737480; called by muse, mutect2, varscan2
- GCM1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 199/434 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs772643207, COSV99452683; called by muse, mutect2, varscan2
- GCNT4 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 182/345 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996742294, COSV59280561; called by muse, mutect2, varscan2
- GFI1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 436/852 reads (51%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.988); catalogued as rs551351361; called by muse, mutect2
- GGT6 | c.1417G>A p.A473T (on ENST00000574154 / NM_001122890.3; = p.A441T on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/810 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.257); catalogued as COSV99041304, COSV99627442; called by muse, mutect2
- GIN1 | c.1103A>G p.H368R | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1554195120; called by muse, mutect2
- GLDC | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 118/435 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757620314, COSV58678697, COSV58683145; called by muse, mutect2, varscan2
- GLI2 | c.3464C>T p.A1155V (on ENST00000361492 / NM_001374353.1; = p.A1172V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 366/723 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as rs759924730, COSV58049010; called by muse, mutect2, varscan2
- GLI3 | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 365/772 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs754391600, COSV67888012; called by muse, mutect2, varscan2
- GLIS3 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 213/450 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.217); catalogued as rs753019404, COSV67946178; called by muse, mutect2, varscan2
- GLMP | c.48dup p.S17Qfs*32 | Frame Shift Ins (INS) | VAF 328/760 reads (43%) | catalogued as rs1251259288; called by mutect2, pindel, varscan2
- GNB4 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 172/370 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs139774004; called by muse, varscan2
- GNPDA1 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 336/650 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs762824840; called by muse, mutect2, varscan2
- GOLGA2 | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 262/560 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs775152615, COSV57851437; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 105/210 reads (50%) | catalogued as rs370114090; called by mutect2, varscan2
- GPBP1L1 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs771524211; called by muse, mutect2, varscan2
- GPR146 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 167/804 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as rs754291447, COSV52467228; called by muse, mutect2, varscan2
- GPR149 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs192779142; called by muse, mutect2, varscan2
- GPR150 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 126/570 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1439000941; called by muse, mutect2, varscan2
- GPRIN1 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 257/885 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs890403395; called by muse, mutect2, varscan2
- GPS2 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 20/360 reads (6%) | catalogued as COSV59750209; called by muse, mutect2
- GPT | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 172/561 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1311002246; called by muse, mutect2, varscan2
- GRAMD1A | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 243/530 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1199512513; called by muse, varscan2
- GREB1L | c.3784G>A p.V1262M | Missense Mutation (SNP) | VAF 370/798 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs541430094; called by muse, mutect2, varscan2
- GRIK5 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 522/1020 reads (51%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.007); catalogued as rs1555870255; called by muse, varscan2
- GRIK5 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 165/399 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as rs774716746, COSV53476009; called by muse, mutect2, varscan2
- GRK5 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 297/582 reads (51%) | catalogued as COSV64865906; called by muse, mutect2, varscan2
- GRM1 | c.446del p.P149Qfs*11 | Frame Shift Del (DEL) | VAF 98/662 reads (15%) | catalogued as rs1207726214, COSV51123015, COSV99267293; called by mutect2, pindel, varscan2
- GRM8 | c.1361G>A p.S454N | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.808); catalogued as rs777966522, COSV58839201; called by muse, varscan2
- GRWD1 | c.807G>A p.W269* | Nonsense Mutation (SNP) | VAF 163/517 reads (32%) | catalogued as rs1368153810; called by muse, mutect2, varscan2
- GTF2IRD1 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 196/433 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1196056898; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2584C>T p.H862Y | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as rs1554454677; called by mutect2, varscan2
- GTF3C1 | c.5326C>T p.R1776C | Missense Mutation (SNP) | VAF 253/554 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746307799, COSV100649644; called by muse, mutect2, varscan2
- GTF3C3 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 140/309 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1246832442; called by muse, varscan2
- GTF3C6 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 224/839 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs901248613; called by muse, mutect2, varscan2
- GUCY2D | c.144del p.A49Pfs*36 | Frame Shift Del (DEL) | VAF 417/881 reads (47%) | catalogued as rs1567956946; called by mutect2, varscan2
- GYS2 | c.1209dup p.L404Tfs*3 | Frame Shift Ins (INS) | VAF 74/232 reads (32%) | catalogued as rs777954647; called by mutect2, varscan2
- H1-6 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 251/506 reads (50%) | catalogued as rs1409708231, COSV58091309; called by muse, mutect2, varscan2
- H2AC1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 82/541 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs760346071, COSV51237380; called by muse, mutect2, varscan2
- H3-3A | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); catalogued as COSV64732350, COSV64734429; called by muse, mutect2, varscan2
- H3C12 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.103); catalogued as COSV58153991; called by muse, mutect2
- H3C12 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 145/305 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as rs1199392510; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 196/499 reads (39%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HCAR3 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 310/688 reads (45%) | catalogued as rs756135211, COSV100811491, COSV63677220; called by muse, varscan2
- HCFC1 | c.3409C>T p.R1137W | Missense Mutation (SNP) | VAF 561/1190 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as rs1043389387, COSV60073377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCK | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 205/728 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs997336181, COSV52944548; called by muse, mutect2, varscan2
- HCN3 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 460/914 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs34277242, COSV64234479; called by muse, varscan2
- HDGFL1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 202/1070 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.094); catalogued as rs1413674258, COSV100014505; called by muse, mutect2, varscan2
- HELT | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 596/1112 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs547106023, COSV58820228; called by muse, mutect2, varscan2
- HERC1 | c.5876A>G p.H1959R | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs776154650; called by muse, mutect2, varscan2
- HGS | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 409/820 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs533048809, COSV61270701; called by muse, mutect2, varscan2
- HIC1 | c.505G>A p.A169T (on ENST00000322941 / NM_001098202.1; = p.A150T on NM_006497.4) | Missense Mutation (SNP) | VAF 418/832 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs1344546752; called by muse, varscan2
- HIF1A | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1251468432, COSV60189211, COSV60191098; called by muse, mutect2, varscan2
- HMCN1 | c.1900T>C p.S634P | Missense Mutation (SNP) | VAF 162/330 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs779907065; called by muse, mutect2, varscan2
- HRH4 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 43/232 reads (19%) | catalogued as rs778017267; called by muse, mutect2, varscan2
- HRNR | c.6338G>A p.S2113N | Missense Mutation (SNP) | VAF 51/1266 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.074); catalogued as rs1387561685; called by muse, mutect2
- HS3ST1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 260/528 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs751861377, COSV99136999; called by muse, varscan2
- HTATSF1 | c.2147A>C p.K716T | Missense Mutation (SNP) | VAF 93/456 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV54480075; called by muse, mutect2, varscan2
- HTR1E | c.801dup p.F268Lfs*4 | Frame Shift Ins (INS) | VAF 93/476 reads (20%) | catalogued as rs753568078; called by mutect2, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 150/601 reads (25%) | catalogued as rs759151580; called by pindel, varscan2
- IDE | c.110del p.K37Rfs*6 | Frame Shift Del (DEL) | VAF 31/209 reads (15%) | catalogued as rs1307048524; called by mutect2, pindel, varscan2
- IGF2BP1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 201/411 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs778356223; called by muse, mutect2, varscan2
- IGFLR1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 284/578 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV53077058; called by muse, mutect2, varscan2
- IGLV2-23 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 162/601 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.02); catalogued as rs763407393; called by muse, mutect2, varscan2
- IGSF10 | c.3110G>A p.S1037N | Missense Mutation (SNP) | VAF 181/350 reads (52%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1052347868; called by muse, mutect2, varscan2
- IGSF8 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 341/669 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs775811812, COSV100081532; called by muse, mutect2, varscan2
- IL11 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 303/642 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.515); catalogued as rs553947830, COSV52772509; called by muse, mutect2, varscan2
- IL1RL2 | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1470741860; called by muse, mutect2, varscan2
- IL6R | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 334/703 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1196450977; called by muse, mutect2, varscan2
- IL9R | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 116/1002 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.423); catalogued as rs372310092; called by mutect2, varscan2
- INHBA | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 117/388 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.482); catalogued as COSV54220904, COSV54224983; called by muse, mutect2, varscan2
- INO80D | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 253/514 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs766341670; called by muse, mutect2
- INPP5F | c.788del p.P263Lfs*7 | Frame Shift Del (DEL) | VAF 52/590 reads (9%) | catalogued as rs750419826; called by mutect2, pindel
- INTS5 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 95/583 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as rs767632603; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 48/210 reads (23%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- INTS7 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99056013; called by muse, mutect2, varscan2
- IQCA1 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 96/219 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs563978762, COSV54502861; called by muse, mutect2, varscan2
- IQCN | c.2419C>T p.Q807* | Nonsense Mutation (SNP) | VAF 147/792 reads (19%) | catalogued as COSV66576449; called by muse, mutect2, varscan2
- IQSEC3 | c.2302G>A p.E768K (on ENST00000538872 / NM_001170738.2; = p.E465K on NM_015232.1) | Missense Mutation (SNP) | VAF 154/853 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as rs782575514, COSV58280759, COSV58281502; called by muse, varscan2
- IRAG2 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as rs954924933; called by muse, mutect2
- IREB2 | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs762002533; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.033); catalogued as rs750024487, COSV56441164; called by muse, mutect2, varscan2
- ITGAV | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as rs376680231; called by muse, mutect2, varscan2
- ITPKC | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 207/390 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1445359994; called by muse, mutect2, varscan2
- IZUMO2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 446/915 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs545804811; called by muse, varscan2
- IZUMO3 | c.574G>A p.V192M (on ENST00000543880 / NM_001365008.2; = p.V186M on NM_001271706.1) | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs1411967945; called by muse, mutect2, varscan2
- KANK3 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 413/828 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs911474222, COSV100445080; called by muse, mutect2, varscan2
- KANSL1 | c.2752G>A p.A918T (on ENST00000574590 / NM_001193465.2; = p.A919T on NM_015443.4) | Missense Mutation (SNP) | VAF 111/706 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs776547113, COSV52240742; ClinVar: likely benign / benign; called by muse, varscan2
- KCNA3 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 238/486 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV63901129; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 320/646 reads (50%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNE5 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 286/634 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV64508705; called by muse, mutect2, varscan2
- KCNQ2 | c.2249G>A p.R750Q (on ENST00000359125 / NM_172107.4; = p.R722Q on NM_004518.6) | Missense Mutation (SNP) | VAF 570/1119 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as rs1372526939; called by muse, mutect2, varscan2
- KCNT2 | c.3349C>T p.R1117* | Nonsense Mutation (SNP) | VAF 131/300 reads (44%) | catalogued as rs761594749, COSV54086794, COSV54091830, COSV54099075; called by muse, mutect2, varscan2
- KCTD16 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 146/328 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750274721, COSV72578748; called by muse, mutect2, varscan2
- KCTD8 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 345/723 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs754941222, COSV63594972; called by muse, mutect2, varscan2
- KDM2A | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 143/751 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1178323458; called by muse, mutect2, varscan2
- KHDRBS2 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 184/668 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1363727004; called by muse, mutect2, varscan2
- KIAA0753 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 128/253 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as rs758932943; called by muse, mutect2, varscan2
- KIF17 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 132/741 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369376665; called by muse, mutect2, varscan2
- KIF1B | c.2989A>G p.S997G (on ENST00000377086 / NM_001365952.1; = p.S951G on NM_015074.3) | Missense Mutation (SNP) | VAF 78/392 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs778056735; called by muse, mutect2, varscan2
- KIF21B | c.1010dup p.N338Qfs*54 | Frame Shift Ins (INS) | VAF 93/445 reads (21%) | catalogued as rs778434242; called by mutect2, pindel, varscan2
- KIF23 | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs374809602; called by muse, mutect2, varscan2
- KIF5A | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 108/645 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs770302674, COSV54057295; called by muse, mutect2, varscan2
- KIFC3 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 259/597 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as COSV65552406; called by muse, mutect2, varscan2
- KIR2DL1 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99383677; called by muse, mutect2, varscan2
- KMT2D | c.4549G>T p.E1517* | Nonsense Mutation (SNP) | VAF 127/567 reads (22%) | catalogued as COSV56427262; called by muse, mutect2, varscan2
- KNDC1 | c.3199A>G p.T1067A | Missense Mutation (SNP) | VAF 532/1075 reads (49%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs746603701; called by muse, mutect2, varscan2
- KRT17 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 76/522 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs1215312325, COSV60861163; called by muse, mutect2, varscan2
- KRT85 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 342/727 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs766037993, COSV57738797; called by muse, mutect2, varscan2
- KRTAP6-1 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 335/666 reads (50%) | PolyPhen probably damaging (0.999); catalogued as COSV58168225; called by muse, mutect2, varscan2
- LARGE2 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 211/794 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs779930770; called by muse, mutect2, varscan2
- LBR | c.967T>C p.Y323H | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as rs757467143; called by muse, varscan2
- LEMD3 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 54/351 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV57650295, COSV57650717; called by muse, mutect2, varscan2
- LENG8 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 316/663 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201939037; called by muse, varscan2
- LGI3 | c.26del p.G9Afs*61 | Frame Shift Del (DEL) | VAF 109/640 reads (17%) | catalogued as rs894404355; called by mutect2, pindel, varscan2
- LILRB3 | c.1904G>A p.S635N (on ENST00000346401; = p.S623N on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 320/664 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1460144141; called by muse, mutect2, varscan2
- LIN54 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 42/634 reads (7%) | catalogued as COSV61201945; called by muse, mutect2
- LIPK | c.331T>C p.Y111H | Missense Mutation (SNP) | VAF 110/494 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762762240; called by muse, mutect2, varscan2
- LIX1L | c.204del p.G69Afs*17 | Frame Shift Del (DEL) | VAF 389/988 reads (39%) | catalogued as rs781851782; called by mutect2, pindel, varscan2
- LMTK3 | c.3338dup p.R1114Pfs*426 | Frame Shift Ins (INS) | VAF 489/1199 reads (41%) | catalogued as rs1437387380; called by mutect2, pindel, varscan2
- LNX1 | c.1835A>G p.N612S (on ENST00000263925 / NM_001126328.3; = p.N516S on NM_032622.2) | Missense Mutation (SNP) | VAF 293/600 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1307930338; called by muse, mutect2, varscan2
- LPIN1 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 274/606 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1230985282, COSV56770230; called by muse, mutect2
- LPIN3 | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 110/548 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs1314321780; called by muse, mutect2, varscan2
- LPXN | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 165/360 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs747896835; called by muse, mutect2, varscan2
- LRMDA | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 138/275 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1171639192; called by muse, mutect2, varscan2
- LRPAP1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 215/466 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs746310452, COSV99579054; called by muse, mutect2, varscan2
- LRRC2 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 128/305 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.749); catalogued as rs755815837; called by muse, mutect2, varscan2
- LRRC47 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 273/559 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs151150139; called by muse, mutect2, varscan2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 72/263 reads (27%) | catalogued as rs749244073; called by mutect2, pindel, varscan2
- LRRN1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 130/272 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.107); catalogued as rs764846311; called by muse, mutect2, varscan2
- LRRN1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 60/374 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs543878366, COSV60016371; called by muse, mutect2, varscan2
- LTB4R2 | c.562G>A p.A188T (on ENST00000528054; = p.A157T on NM_019839.5) | Missense Mutation (SNP) | VAF 239/1190 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); catalogued as rs773532640; called by muse, mutect2, varscan2
- LTBP2 | c.5020del p.A1674Pfs*67 | Frame Shift Del (DEL) | VAF 251/1031 reads (24%) | catalogued as rs761199739; called by mutect2, pindel, varscan2
- LTBP2 | c.3822G>A p.W1274* | Nonsense Mutation (SNP) | VAF 88/459 reads (19%) | catalogued as rs777797706; called by muse, mutect2, varscan2
- LTN1 | c.3351del p.P1118Hfs*2 | Frame Shift Del (DEL) | VAF 46/173 reads (27%) | catalogued as rs988262129; called by pindel, varscan2
- LYPD3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 106/474 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs766141899; called by muse, mutect2, varscan2
- MAD1L1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 179/523 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs746977336; called by muse, mutect2, varscan2
- MAFK | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 450/901 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs768259709, COSV52473079; called by muse, mutect2, varscan2
- MAGEB3 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 219/442 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs780082636, COSV100854839, COSV64396902; called by muse, mutect2, varscan2
- MAGEB4 | c.797del p.P266Hfs*18 | Frame Shift Del (DEL) | VAF 266/663 reads (40%) | catalogued as COSV66775264, COSV66776807; called by mutect2, pindel, varscan2
- MAMDC4 | c.2539G>T p.D847Y (on ENST00000445819; = p.D768Y on NM_206920.3) | Missense Mutation (SNP) | VAF 176/686 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56375152; called by muse, mutect2, varscan2
- MAP3K11 | c.2428G>C p.D810H | Missense Mutation (SNP) | VAF 482/976 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as COSV58421453; called by muse, mutect2, varscan2
- MAP3K14 | c.2027C>A p.P676Q | Missense Mutation (SNP) | VAF 272/570 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV60922773; called by muse, varscan2
- MAP3K8 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 212/469 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.764); catalogued as rs532844555, COSV53920720; called by muse, mutect2, varscan2
- MARCHF3 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 308/666 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370472268; called by muse, mutect2, varscan2
- MARCHF6 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 97/536 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs200089051; called by muse, mutect2, varscan2
- MARCKS | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 139/888 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as rs775771344; called by muse, mutect2, varscan2
- MASP1 | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 191/375 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV51459581; called by muse, mutect2, varscan2
- MATN2 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 141/312 reads (45%) | catalogued as rs1399337651; called by muse, mutect2, varscan2
- MATN3 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 66/382 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV68100209; called by muse, mutect2, varscan2
- MC1R | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 155/905 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs117952179; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 76/161 reads (47%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MEGF6 | c.1763del p.G588Vfs*123 | Frame Shift Del (DEL) | VAF 87/587 reads (15%) | catalogued as rs1448789220; called by mutect2, pindel, varscan2
- MEGF8 | c.6575C>T p.T2192M (on ENST00000251268 / NM_001271938.2; = p.T2125M on NM_001410.3) | Missense Mutation (SNP) | VAF 408/856 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs367956687; called by muse, mutect2, varscan2
- MEIS1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 296/652 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV55486377; called by muse, varscan2
- MELTF | c.1916A>G p.Y639C | Missense Mutation (SNP) | VAF 78/516 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs781461188; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 48/216 reads (22%) | catalogued as rs780635289; called by mutect2, varscan2
- MGAT4C | c.1151A>G p.E384G | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV59838928; called by muse, mutect2
- MIA2 | c.1321_1323del p.E441del | In Frame Del (DEL) | VAF 64/147 reads (44%) | catalogued as rs768942458; called by pindel, varscan2
- MIIP | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 79/497 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.357); catalogued as rs1378735329; called by muse, mutect2, varscan2
- MKRN3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs377353800; called by muse, mutect2, varscan2
- MMP17 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 506/1044 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs758660100, COSV100861844; called by muse, mutect2, varscan2
- MMP25 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 436/798 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs755730588; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 64/155 reads (41%) | catalogued as rs755830405; called by mutect2, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 74/226 reads (33%) | catalogued as rs753079987; called by mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 34/150 reads (23%) | catalogued as rs757379917; called by mutect2, varscan2
- MTRF1L | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755413374; called by muse, mutect2, varscan2
- MTUS2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 222/502 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373199820; called by muse, mutect2, varscan2
- MUC1 | c.3441C>T p.S1147= (on ENST00000611571 / NM_001371720.1; = p.S158= on NM_002456.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 179/375 reads (48%) | catalogued as rs766729514; called by muse, mutect2, varscan2
- MUC16 | c.22162G>T p.E7388* | Nonsense Mutation (SNP) | VAF 216/490 reads (44%) | catalogued as COSV101200516; called by muse, varscan2
- MUC2 | c.2926C>T p.R976W | Missense Mutation (SNP) | VAF 206/732 reads (28%) | SIFT deleterious (0); catalogued as rs747688546; called by muse, mutect2, varscan2
- MUC6 | c.1094T>C p.M365T | Missense Mutation (SNP) | VAF 473/933 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs753396750; called by muse, mutect2, varscan2
- MX2 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 239/508 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1239092598; called by muse, mutect2, varscan2
- MXRA5 | c.8366T>C p.L2789P | Missense Mutation (SNP) | VAF 417/832 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99478379; called by muse, mutect2, varscan2
- MYH3 | c.4190G>A p.R1397H | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs1301679193; called by muse, mutect2, varscan2
- MYH7B | c.5233C>T p.R1745C | Missense Mutation (SNP) | VAF 393/798 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs528383184; called by muse, mutect2, varscan2
- MYO18B | c.6067T>C p.Y2023H | Missense Mutation (SNP) | VAF 138/616 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59142347; called by muse, mutect2, varscan2
- MYO1F | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 438/830 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776629967; called by muse, mutect2, varscan2
- NAALADL2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs575644923, COSV69154945; called by muse, mutect2, varscan2
- NACC1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 414/818 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs745831202, COSV52834742; called by muse, mutect2, varscan2
- NAV1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 406/801 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs751806991, COSV55218445; called by muse, mutect2, varscan2
- NBEA | c.8014G>A p.V2672I | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1422355070, COSV59830002; called by muse, mutect2, varscan2
- NBPF10 | c.11065del p.R3689Efs*32 | Frame Shift Del (DEL) | VAF 35/106 reads (33%) | catalogued as rs781875736; called by mutect2, pindel, varscan2
- NCK2 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 253/531 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs745514962; called by muse, mutect2, varscan2
- NCKAP5 | c.3863C>T p.T1288M | Missense Mutation (SNP) | VAF 256/551 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as rs765048071, COSV58445155; called by muse, mutect2, varscan2
- NCOR2 | c.2956del p.R986Gfs*77 | Frame Shift Del (DEL) | VAF 303/902 reads (34%) | catalogued as rs746871841; called by pindel, varscan2
- NEFM | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 452/870 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs372487174; called by muse, mutect2, varscan2
- NEK10 | c.2011G>A p.V671I | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1233913000, COSV58279860; called by muse, mutect2, varscan2
- NELFCD | c.791del p.G264Afs*27 (on ENST00000602795; = p.G246Afs*27 on NM_198976.4) | Frame Shift Del (DEL) | VAF 357/919 reads (39%) | catalogued as rs920632659; called by mutect2, pindel, varscan2
- NELL2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.852); catalogued as rs774686363; called by muse, mutect2, varscan2
- NETO1 | c.191del p.P64Lfs*9 | Frame Shift Del (DEL) | VAF 114/334 reads (34%) | catalogued as COSV55005165; called by pindel, varscan2
- NGFR | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 107/554 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs1308452489, COSV50804849; called by muse, mutect2, varscan2
- NKAPL | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 369/739 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59196948; called by muse, mutect2, varscan2
- NKD2 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 587/1183 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs532972203; called by muse, varscan2
- NKTR | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 108/227 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs746342809; called by muse, mutect2, varscan2
- NKTR | c.4069C>T p.R1357W | Missense Mutation (SNP) | VAF 78/336 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs201002171; called by muse, mutect2, varscan2
- NKX6-3 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 336/688 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as rs1205383114, COSV57012439; called by muse, mutect2, varscan2
- NLGN4X | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 129/284 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569195407, COSV52011605; called by muse, mutect2, varscan2
- NLRP5 | c.1950G>T p.E650D | Missense Mutation (SNP) | VAF 298/632 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs762526958; called by muse, mutect2, varscan2
- NLRP6 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 261/1016 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56462497; called by muse, mutect2, varscan2
- NOA1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 151/828 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV99950496; called by muse, mutect2, varscan2
- NOL8 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 86/422 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs200196088, COSV100694521; called by muse, mutect2, varscan2
- NOS2 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58223006; called by muse, varscan2
- NOTCH1 | c.5629C>T p.R1877C | Missense Mutation (SNP) | VAF 270/551 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1446708596, COSV53052835, COSV53103129; called by muse, mutect2, varscan2
- NOTCH2 | c.6998C>T p.A2333V | Missense Mutation (SNP) | VAF 383/820 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs768047492, COSV56701788; called by muse, mutect2, varscan2
- NPAS3 | c.1189C>T p.R397C (on ENST00000356141 / NM_001164749.2; = p.R365C on NM_022123.3) | Missense Mutation (SNP) | VAF 106/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60837091; called by muse, mutect2, varscan2
- NPTX1 | c.573del p.R192Gfs*14 | Frame Shift Del (DEL) | VAF 423/1034 reads (41%) | catalogued as COSV100151049; called by mutect2, pindel, varscan2
- NR1H2 | c.37del p.L13Cfs*18 | Frame Shift Del (DEL) | VAF 307/757 reads (41%) | catalogued as COSV53799939; called by mutect2, pindel, varscan2
- NR1H3 | c.601del p.Q201Kfs*13 | Frame Shift Del (DEL) | VAF 389/783 reads (50%) | catalogued as rs779801455; called by mutect2, varscan2
- NTHL1 | c.555G>T p.K185N (on ENST00000219066; = p.K177N on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/509 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54592477; called by muse, mutect2, varscan2
- NTSR2 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 416/832 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1199690450; called by muse, varscan2
- NUDT5 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 221/442 reads (50%) | catalogued as rs779037273, COSV66718236; called by muse, mutect2, varscan2
- NUFIP2 | c.1295dup p.Q433Sfs*9 | Frame Shift Ins (INS) | VAF 131/355 reads (37%) | catalogued as rs1253107931; called by mutect2, pindel, varscan2
- NUP133 | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 162/558 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369761150; called by muse, mutect2, varscan2
- NWD2 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 130/629 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs893111904; called by muse, mutect2, varscan2
- NYAP2 | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 425/859 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752903462, COSV56004733; called by muse, mutect2, varscan2
- NYX | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 222/1144 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs139601761, COSV61181120; called by muse, mutect2, varscan2
- OBSCN | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 281/942 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs1426564242; called by muse, varscan2
- OBSCN | c.11753C>T p.A3918V | Missense Mutation (SNP) | VAF 161/841 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.38); catalogued as COSV104371788; called by muse, mutect2, varscan2
- OBSCN | c.11948G>T p.R3983L | Missense Mutation (SNP) | VAF 302/611 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV52749131; called by muse, mutect2, varscan2
- OBSCN | c.12512C>T p.T4171M | Missense Mutation (SNP) | VAF 279/644 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); catalogued as rs778801081, COSV52788497; called by muse, mutect2, varscan2
- OFD1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 29/530 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60795267; called by muse, mutect2
- OGFR | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 198/1022 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1232553157; called by muse, varscan2
- OLFM1 | c.467C>T p.A156V (on ENST00000371793 / NM_001282611.2; = p.A138V on NM_014279.5) | Missense Mutation (SNP) | VAF 149/331 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.137); catalogued as rs752852516, COSV99424129; called by muse, mutect2, varscan2
- OLFM2 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 238/512 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227359313; called by muse, mutect2, varscan2
- OLR1 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 125/298 reads (42%) | catalogued as rs374394285; called by muse, mutect2, varscan2
- OPLAH | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 378/771 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs868953913, COSV70678441; called by muse, mutect2, varscan2
- OPRPN | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 291/568 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777093106, COSV101271071; called by muse, mutect2, varscan2
- OR10AC1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 563/1173 reads (48%) | catalogued as rs1004270110; called by muse, mutect2, varscan2
- OR10G2 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 126/484 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs746330187, COSV101606933; called by muse, mutect2
- OR1S1 | c.821del p.F274Sfs*21 | Frame Shift Del (DEL) | VAF 84/323 reads (26%) | catalogued as rs751375371; called by mutect2, varscan2
- OR2D2 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 127/285 reads (45%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.548); catalogued as COSV55057731; called by muse, mutect2, varscan2
- OR2H1 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 38/904 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1221844233, COSV101009896; called by muse, mutect2
- OR2M7 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs143090101, COSV58740084; called by muse, mutect2, varscan2
- OR2T35 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 175/500 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.408); catalogued as rs781562747; called by muse, mutect2, varscan2
- OR52E6 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 148/364 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs751110463; called by muse, mutect2
- OR5I1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 151/334 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs1439449796; called by muse, mutect2, varscan2
- OSCAR | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 126/715 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs986512406, COSV52926861; called by muse, mutect2, varscan2
- OTOP2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 271/914 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as rs148548570; called by muse, mutect2, varscan2
- PACSIN1 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 339/715 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1386348550, COSV55058830; called by muse, mutect2, varscan2
- PALLD | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 154/310 reads (50%) | catalogued as COSV99825699; called by muse, varscan2
- PALM | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 500/1044 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); catalogued as rs199827121; called by muse, mutect2, varscan2
- PANX2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 520/1003 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs1488640466, COSV50292514; called by muse, mutect2, varscan2
- PARP15 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.224); catalogued as rs1196652616; called by muse, mutect2, varscan2
- PARVB | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 270/582 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as rs201726985; called by muse, varscan2
- PAX1 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 257/807 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1438721936; called by muse, mutect2, varscan2
- PCDH11X | c.2595A>G p.I865M | Missense Mutation (SNP) | VAF 214/422 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV100011432; called by muse, mutect2, varscan2
- PCDH7 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 211/945 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs551643639; called by muse, mutect2, varscan2
- PCDHA10 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs782288464, COSV100253124; called by muse, mutect2
- PCDHA11 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 153/547 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.684); catalogued as rs1243170344; called by muse, mutect2, varscan2
- PCDHA3 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 38/1258 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs373853046; called by muse, mutect2
- PCDHB5 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 570/1149 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as COSV50655031; called by muse, mutect2, varscan2
- PCDHGA3 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 475/983 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV53923997; called by muse, mutect2, varscan2
- PCDHGA3 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 228/1144 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.185); catalogued as rs745349592, COSV53916955, COSV54017901; called by muse, mutect2, varscan2
- PCDHGA8 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 228/486 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1406338034; called by muse, mutect2, varscan2
- PCDHGB1 | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 66/756 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs756809121; called by muse, mutect2
- PCDHGB4 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 129/482 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99547665; called by muse, mutect2, varscan2
- PCLO | c.5527C>T p.R1843C | Missense Mutation (SNP) | VAF 176/355 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934051413, COSV61648684; called by muse, mutect2, varscan2
- PCNX2 | c.1856del p.K619Rfs*52 | Frame Shift Del (DEL) | VAF 40/292 reads (14%) | catalogued as COSV50784264; called by mutect2, varscan2
- PCSK5 | c.4694G>A p.R1565Q | Missense Mutation (SNP) | VAF 89/496 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs768920911, COSV101377545, COSV104436789; called by muse, mutect2, varscan2
- PDIA4 | c.1819G>A p.A607T (on ENST00000286091 / NM_001371244.1; = p.A606T on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 279/556 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs371145672, COSV99618410; called by muse, mutect2, varscan2
- PDSS1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 146/324 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs780198984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDZK1IP1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 109/601 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs759931017; called by muse, mutect2, varscan2
- PEG3 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 162/386 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); catalogued as COSV55636345; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 207/448 reads (46%) | catalogued as rs752653446, COSV99342923; called by mutect2, varscan2
- PEX16 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 297/592 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769772100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEX19 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 211/476 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs370126224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PFKFB1 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 165/346 reads (48%) | PolyPhen probably damaging (0.999); catalogued as rs368958510, COSV66629156; called by muse, mutect2, varscan2
- PGBD1 | c.1645A>G p.M549V | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs774771086; called by muse, mutect2, varscan2
- PHF12 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs565143464; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 54/303 reads (18%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PI4KA | c.5386C>T p.Q1796* | Nonsense Mutation (SNP) | VAF 168/612 reads (27%) | catalogued as rs62619942, COSV55424326; called by muse, mutect2, varscan2
- PICK1 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 114/539 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs771440049, COSV100811113; called by muse, mutect2, varscan2
- PIEZO2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.598); catalogued as rs879674484, COSV57433467; called by muse, mutect2, varscan2
- PIGG | c.2142G>T p.R714S (on ENST00000453061 / NM_001127178.3; = p.R706S on NM_017733.4) | Missense Mutation (SNP) | VAF 383/812 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs769065983, COSV99573740; called by muse, mutect2, varscan2
- PKD1 | c.3934C>T p.R1312W | Missense Mutation (SNP) | VAF 349/781 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs755661885; called by muse, mutect2, varscan2
- PKHD1L1 | c.4388C>G p.T1463R | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV101006808; called by muse, mutect2, varscan2
- PKIB | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 301/712 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752581156, COSV99236149; called by muse, mutect2, varscan2
- PLA2G6 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 298/610 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.138); catalogued as rs57170315; called by muse, mutect2, varscan2
- PLCB3 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 65/486 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1387966146, COSV54189449; called by muse, mutect2, varscan2
- PLCB3 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 276/650 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs150574710; called by muse, mutect2, varscan2
- PLEC | c.1333C>A p.P445T (on ENST00000322810 / NM_201380.4; = p.P335T on NM_000445.5) | Missense Mutation (SNP) | VAF 61/649 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV59656687; called by muse, mutect2
- PLEK | c.695A>G p.D232G | Missense Mutation (SNP) | VAF 162/362 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs751465412, COSV52250484; called by muse, mutect2, varscan2
- PLEKHG1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 195/402 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772673577, COSV62045461; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 403/949 reads (42%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PLEKHM2 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 151/781 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as rs1161474873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLOD1 | c.1095C>T p.G365= | Splice Region (SNP) | VAF 89/418 reads (21%) | catalogued as rs1032781250, CS003903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA4 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 205/724 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.425); catalogued as rs751969293, COSV58122840; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 250/977 reads (26%) | catalogued as rs953293505; called by mutect2, pindel, varscan2
- PMPCA | c.415A>G p.I139V | Missense Mutation (SNP) | VAF 153/311 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1280678675; called by muse, mutect2, varscan2
- PNPLA1 | c.1319G>A p.R440Q (on ENST00000394571 / NM_001374623.1; = p.R345Q on NM_173676.2) | Missense Mutation (SNP) | VAF 342/715 reads (48%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs144648025; called by muse, mutect2
- PODN | c.908C>G p.P303R (on ENST00000395871; = p.P255R on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 258/528 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs200853703, COSV100439932, COSV57012343; called by muse, varscan2
- POLB | c.485T>A p.V162E | Missense Mutation (SNP) | VAF 121/229 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV55345500; called by muse, mutect2, varscan2
- POM121C | c.3497A>G p.N1166S (on ENST00000607367; = p.N924S on NM_001099415.3) | Missense Mutation (SNP) | VAF 83/610 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as rs1358874890; called by muse, mutect2, varscan2
- POU3F4 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 102/576 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV64540079; called by muse, mutect2, varscan2
- POU4F2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 445/864 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV99850545; called by muse, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 63/244 reads (26%) | catalogued as rs775130624; called by mutect2, varscan2
- PPL | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 229/473 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as rs749601480, COSV62044746; called by muse, mutect2, varscan2
- PPP1R37 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 457/908 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.037); catalogued as rs1400599286; called by muse, mutect2, varscan2
- PPP2R5C | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 63/619 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.117); catalogued as rs748312635; called by muse, varscan2
- PRDM1 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 223/876 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); catalogued as rs762241140, COSV64846343; called by muse, mutect2, varscan2
- PRDM10 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 147/299 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs759125313, COSV58799041; called by muse, varscan2
- PREX2 | c.1693dup p.S565Ffs*3 | Frame Shift Ins (INS) | VAF 30/232 reads (13%) | catalogued as rs764112302; called by mutect2, varscan2
- PRKAA2 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs566846969; called by muse, mutect2, varscan2
- PRKN | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759676993; called by muse, mutect2, varscan2
- PRM3 | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 408/846 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.178); catalogued as rs748507374, COSV99617551; called by muse, varscan2
- PRODH2 | c.250C>T p.L84F (on ENST00000301175; = p.L8F on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 366/771 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.726); catalogued as rs539737639; called by muse, mutect2, varscan2
- PROS1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 161/310 reads (52%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs1339385324; called by muse, mutect2, varscan2
- PRRT1B | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 324/686 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs759826913; called by muse, mutect2, varscan2
- PSMC5 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 208/413 reads (50%) | catalogued as rs1320796271; called by muse, varscan2
- PSMD1 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 50/274 reads (18%) | catalogued as COSV58077369; called by muse, mutect2, varscan2
- PTCHD4 | c.2288T>A p.V763D | Missense Mutation (SNP) | VAF 178/369 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.393); catalogued as COSV59779712; called by muse, mutect2, varscan2
- PTOV1 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 423/832 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs763356063; called by muse, mutect2, varscan2
- PTPN21 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 463/1193 reads (39%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs749109098, COSV60846625; called by muse, mutect2, varscan2
- PTPN22 | c.1612del p.S538Hfs*49 (on ENST00000359785 / NM_001193431.2; = p.S483Hfs*49 on NM_012411.5) | Frame Shift Del (DEL) | VAF 76/293 reads (26%) | catalogued as rs1558030958; called by mutect2, pindel, varscan2
- PTPN4 | c.2242A>G p.M748V | Missense Mutation (SNP) | VAF 147/290 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1313028128; called by muse, mutect2, varscan2
- PTPRS | c.1865del p.P622Lfs*16 | Frame Shift Del (DEL) | VAF 57/194 reads (29%) | catalogued as rs755108907; called by mutect2, pindel, varscan2
- PURA | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 300/572 reads (52%) | catalogued as COSV58762812; called by muse, varscan2
- PURA | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 65/903 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561793272; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- PUSL1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 324/634 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs778378455; called by muse, mutect2, varscan2
- R3HCC1L | c.1564C>A p.L522I | Missense Mutation (SNP) | VAF 112/228 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as rs76898723; called by muse, mutect2, varscan2
- RAB44 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 45/754 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs564653772, COSV57712598; called by muse, mutect2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 122/290 reads (42%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RABL2B | c.430del p.S144Afs*24 | Frame Shift Del (DEL) | VAF 141/378 reads (37%) | catalogued as rs781940096; called by mutect2, pindel, varscan2
- RAPGEF5 | c.1463del p.K488Rfs*2 (on ENST00000401957 / NM_001367602.2; = p.K791Rfs*2 on NM_012294.5) | Frame Shift Del (DEL) | VAF 127/309 reads (41%) | catalogued as rs1562708461; called by mutect2, pindel, varscan2
- RASL12 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 374/738 reads (51%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV54981145; called by muse, mutect2, varscan2
- RAVER2 | c.2060del p.K687Rfs*15 (on ENST00000294428 / NM_001366165.1; = p.K674Rfs*15 on NM_018211.4) | Frame Shift Del (DEL) | VAF 77/289 reads (27%) | catalogued as COSV53805154; called by mutect2, pindel, varscan2
- RBKS | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 190/404 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs753654813, COSV56221039; called by muse, mutect2, varscan2
- RBM28 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 314/620 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs773917237; called by muse, varscan2
- RBMX | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 146/300 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV57810783; called by muse, mutect2, varscan2
- RCBTB2 | c.298dup p.I100Nfs*27 | Frame Shift Ins (INS) | VAF 162/344 reads (47%) | catalogued as rs767856805; called by mutect2, varscan2
- REEP4 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 322/704 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.622); catalogued as rs138652730; called by muse, mutect2, varscan2
- REV3L | c.4873del p.S1625Qfs*28 | Frame Shift Del (DEL) | VAF 42/219 reads (19%) | catalogued as rs1381009149; called by mutect2, pindel, varscan2
- REXO1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 56/1140 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs369050979; called by muse, mutect2
- RFPL1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 116/851 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs752820179, COSV62978365; called by muse, mutect2
- RGL3 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 397/788 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1340204059, COSV63387053; called by muse, mutect2, varscan2
- RGSL1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1219696801, COSV54262523; called by muse, mutect2
- RHBDD2 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 31/958 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs782157883; called by muse, mutect2
- RIMS1 | c.3946C>T p.R1316C | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs749244330, COSV53461711; called by muse, mutect2, varscan2
- RNASE3 | c.143del p.P48Lfs*31 | Frame Shift Del (DEL) | VAF 88/726 reads (12%) | catalogued as COSV58959173; called by mutect2, pindel, varscan2
- RNF157 | c.1558A>G p.M520V | Missense Mutation (SNP) | VAF 21/536 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99487146; called by muse, mutect2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 66/180 reads (37%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- RPL39L | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1036804831; called by muse, mutect2, varscan2
- RPRM | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 24/896 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1486207949; called by muse, mutect2
- RPS6 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 244/460 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1386751153; called by muse, mutect2, varscan2
- RREB1 | c.2473G>A p.V825M | Missense Mutation (SNP) | VAF 563/1059 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs746526434; called by muse, mutect2, varscan2
- RRS1 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 130/772 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.133); catalogued as COSV52559840; called by muse, mutect2, varscan2
- RS1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 315/668 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV66106045; called by muse, mutect2, varscan2
- RSPH3 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 182/604 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.483); catalogued as rs1268142382; called by muse, mutect2, varscan2
- RSRC2 | c.1217A>G p.Q406R | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV59202836; called by muse, mutect2
- RTP1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 151/346 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs369064403; called by muse, mutect2, varscan2
- RUFY4 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 161/371 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as rs760520417, COSV60250370; called by muse, varscan2
- RUNDC3B | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 144/759 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs369026321, COSV99712772; called by muse, mutect2, varscan2
- RYK | c.1280G>A p.R427Q (on ENST00000620660 / NM_001005861.2; = p.R424Q on NM_002958.4) | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs747240194; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 302/760 reads (40%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SAMD11 | c.1237del p.Q413Rfs*38 | Frame Shift Del (DEL) | VAF 466/1166 reads (40%) | catalogued as rs1223597129; called by mutect2, pindel, varscan2
- SBF2 | c.4984C>T p.Q1662* | Nonsense Mutation (SNP) | VAF 94/489 reads (19%) | catalogued as COSV56313820; called by muse, mutect2, varscan2
- SCAMP2 | c.223del p.Q75Rfs*36 | Frame Shift Del (DEL) | VAF 233/537 reads (43%) | catalogued as rs1304394803, COSV51513780; called by mutect2, pindel, varscan2
- SCML1 | c.5T>C p.M2T | Missense Mutation (SNP) | VAF 161/310 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs1397704267; called by muse, mutect2, varscan2
- SCN7A | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200874141; called by muse, mutect2
- SCN9A | c.3230A>G p.Q1077R (on ENST00000303354; = p.Q1066R on NM_002977.3) | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs1269109229; called by muse, mutect2
- SDR42E1 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.173); catalogued as rs1189614892; called by muse, mutect2, varscan2
- SEC14L5 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 321/660 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs961539113, COSV52037943; called by muse, mutect2, varscan2
- SEC16B | c.2864G>A p.G955D | Missense Mutation (SNP) | VAF 272/618 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100381865; called by muse, mutect2, varscan2
- SEH1L | c.31C>A p.H11N | Missense Mutation (SNP) | VAF 168/727 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100040171; called by muse, mutect2, varscan2
- SELENON | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 369/716 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1381957995; called by muse, mutect2, varscan2
- SEMA6D | c.2339T>G p.L780R (on ENST00000316364 / NM_153618.2; = p.L718R on NM_020858.2) | Missense Mutation (SNP) | VAF 93/463 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100316601; called by muse, mutect2, varscan2
- SENP6 | c.1024_1026del p.N342del | In Frame Del (DEL) | VAF 22/161 reads (14%) | catalogued as rs1351545932; called by mutect2, pindel, varscan2
- SERPINB8 | c.575dup p.T193Dfs*7 | Frame Shift Ins (INS) | VAF 112/216 reads (52%) | catalogued as rs1568275935; called by mutect2, varscan2
- SETD5 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 244/472 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775813972; called by muse, mutect2, varscan2
- SETDB2 | c.14dup p.N5Kfs*14 | Frame Shift Ins (INS) | VAF 46/184 reads (25%) | catalogued as rs1288692615; called by mutect2, varscan2
- SFSWAP | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 262/544 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV55520691; called by muse, mutect2
- SGF29 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 309/631 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1049141877, COSV57681306; called by muse, mutect2, varscan2
- SH2D3A | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 216/478 reads (45%) | catalogued as rs765689594, COSV55586367, COSV55588318; called by muse, mutect2, varscan2
- SH3RF3 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 325/706 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs750908319; called by muse, mutect2, varscan2
- SHANK1 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 145/672 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as rs771901125, COSV53248013; called by muse, mutect2, varscan2
- SHF | c.102del p.K35Rfs*4 | Frame Shift Del (DEL) | VAF 413/1018 reads (41%) | catalogued as rs1359127581; called by mutect2, pindel, varscan2
- SHISA7 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 166/893 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs1023953712; called by muse, mutect2, varscan2
- SHROOM3 | c.5707C>T p.R1903* | Nonsense Mutation (SNP) | VAF 141/504 reads (28%) | catalogued as COSV56031526; called by muse, mutect2, varscan2
- SIDT2 | c.1964T>C p.M655T | Missense Mutation (SNP) | VAF 237/508 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54059092; called by muse, mutect2, varscan2
- SIPA1 | c.1954G>A p.G652S | Missense Mutation (SNP) | VAF 482/986 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1045285740; called by muse, varscan2
- SKI | c.1463G>A p.S488N | Missense Mutation (SNP) | VAF 207/450 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs763580567; called by muse, mutect2, varscan2
- SLAIN1 | c.1553G>A p.R518H (on ENST00000466548; = p.R255H on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/407 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764341266, COSV57385488, COSV57389537; called by muse, mutect2, varscan2
- SLC16A2 | c.489A>G p.I163M | Missense Mutation (SNP) | VAF 29/802 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs1283872852; called by muse, mutect2
- SLC22A7 | c.1240G>A p.A414T (on ENST00000372585 / NM_153320.2; = p.A412T on NM_006672.3) | Missense Mutation (SNP) | VAF 93/609 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs1211079819; called by muse, mutect2, varscan2
- SLC22A7 | c.1519G>A p.G507S (on ENST00000372585 / NM_153320.2; = p.G505S on NM_006672.3) | Missense Mutation (SNP) | VAF 329/689 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs375391589; called by muse, varscan2
- SLC26A7 | c.58del p.Q20Sfs*24 | Frame Shift Del (DEL) | VAF 129/332 reads (39%) | catalogued as rs749030792; called by mutect2, pindel, varscan2
- SLC27A3 | c.2221T>G p.L741V (on ENST00000271857; = p.L613V on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 344/755 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs746234303; called by muse, mutect2, varscan2
- SLC2A8 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 320/646 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV64894436; called by muse, mutect2, varscan2
- SLC37A1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 134/447 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1264470149, COSV61404975; called by muse, mutect2, varscan2
- SLC44A2 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 76/438 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV59836779; called by muse, mutect2, varscan2
- SLC44A5 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1336961196, COSV63757987; called by muse, mutect2, varscan2
- SLC4A11 | c.1426T>C p.F476L | Missense Mutation (SNP) | VAF 256/536 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66261504; called by muse, mutect2, varscan2
- SLC5A4 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 172/401 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs749298344, COSV99832260; called by muse, mutect2, varscan2
- SLC6A13 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 305/565 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs140808969, COSV58258894; called by muse, mutect2, varscan2
- SLC9A1 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 383/804 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as rs996560889, COSV56052534; called by muse, mutect2, varscan2
- SLC9A3R1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 151/461 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.304); catalogued as rs150507328; called by muse, mutect2, varscan2
- SLC9C1 | c.3284C>T p.P1095L | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as rs573214446; called by muse, mutect2, varscan2
- SLCO6A1 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 129/262 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV101134911; called by muse, mutect2, varscan2
- SLIT2 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 150/691 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56589359; called by muse, varscan2
- SLIT3 | c.4125C>T p.H1375= | Splice Region (SNP) | VAF 101/480 reads (21%) | catalogued as rs763813873; called by muse, mutect2, varscan2
- SLITRK2 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 368/747 reads (49%) | catalogued as COSV59423547; called by muse, mutect2, varscan2
- SMARCA4 | c.3539C>A p.P1180H | Missense Mutation (SNP) | VAF 211/433 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60787385, COSV60793319; called by muse, mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SMG8 | c.2909del p.P970Lfs*7 | Frame Shift Del (DEL) | VAF 191/482 reads (40%) | catalogued as COSV56284374; called by mutect2, pindel, varscan2
- SMO | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 182/429 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs758800465, COSV99976685; called by muse, mutect2, varscan2
- SMPD1 | c.1053G>T p.W351C | Missense Mutation (SNP) | VAF 332/626 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100192576; called by muse, mutect2, varscan2
- SMYD3 | c.1085del p.F362Sfs*12 (on ENST00000490107 / NM_001375962.1; = p.F303Sfs*12 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/282 reads (12%) | catalogued as COSV63628704; called by mutect2, varscan2
- SNTG2 | c.26del p.P9Rfs*37 | Frame Shift Del (DEL) | VAF 304/838 reads (36%) | catalogued as rs1340065510; called by pindel, varscan2
- SNX20 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 193/1070 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV56057536; called by muse, mutect2, varscan2
- SORL1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 125/547 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs564006388, COSV52752171; called by muse, mutect2, varscan2
- SOS2 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751240491, COSV99365858; called by muse, mutect2, varscan2
- SPANXN3 | c.272T>C p.L91S | Missense Mutation (SNP) | VAF 242/474 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs868913972; called by muse, mutect2, varscan2
- SPANXN4 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 175/360 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as COSV100981016, COSV65141596; called by muse, mutect2, varscan2
- SPATC1 | c.1017del p.A340Pfs*76 | Frame Shift Del (DEL) | VAF 262/493 reads (53%) | catalogued as COSV101085355; called by mutect2, varscan2
- SPECC1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 180/382 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs190108325, COSV54967526; called by muse, mutect2, varscan2
- SPNS3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 337/657 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs781408944; called by muse, mutect2, varscan2
- SPPL2B | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 191/421 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs748378324; called by muse, mutect2, varscan2
- SPRYD3 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 185/618 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.799); catalogued as COSV56853475; called by muse, mutect2, varscan2
- SPTBN2 | c.4402_4404del p.E1468del | In Frame Del (DEL) | VAF 126/751 reads (17%) | catalogued as rs1249538982; called by pindel, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 147/324 reads (45%) | catalogued as rs748467821; called by mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 42/106 reads (40%) | catalogued as rs750306056; called by mutect2, varscan2
- SRPX | c.1294C>A p.L432M | Missense Mutation (SNP) | VAF 340/632 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as rs1286313792; called by muse, mutect2
- SRRM4 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 141/671 reads (21%) | catalogued as rs373815603, COSV57414549; called by muse, mutect2, varscan2
- SRSF6 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 152/356 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs148216368; called by muse, mutect2, varscan2
- SSH2 | c.2756del p.P919Qfs*12 | Frame Shift Del (DEL) | VAF 70/491 reads (14%) | catalogued as rs752567808; called by pindel, varscan2
1,886 further variants in this file (1,183 protein-altering or splice-affecting, 591 silent, 112 other) are not listed here.
